Somatic mutation profile of tumor specimen TCGA-49-4506-01A (aliquot TCGA-49-4506-01A-01D-1265-08) from TCGA case TCGA-49-4506, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.8 years (25,132 days).
Specimen TCGA-49-4506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 444442c1-32a6-4b64-bbb4-831f22aa00a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4506-11A (Solid Tissue Normal), aliquot TCGA-49-4506-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dc53ea5-9b08-4355-b68c-3c145730986b

The open-access MAF lists 121 somatic variants for this specimen: 93 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 27, Nonsense Mutation 12, Frame Shift Ins 3, Splice Region 2, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL3 | c.3940G>T p.G1314* | Nonsense Mutation (SNP) | VAF 45/242 reads (19%) | catalogued as COSV54435475; called by muse, mutect2, varscan2
- AFAP1L2 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100412520, COSV58412119; called by muse, mutect2, varscan2
- APOA5 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV57062168; called by muse, mutect2, varscan2
- ASH1L | c.5377C>T p.H1793Y | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV64205227; called by muse, mutect2
- C16orf72 | c.581A>C p.H194P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100588991; called by muse, mutect2, varscan2
- CASS4 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100824576; called by muse, mutect2
- CDH9 | c.1993G>T p.G665W | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50251232, COSV50257769, COSV99039254; called by muse, mutect2
- COL3A1 | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV58581558; called by muse, mutect2, varscan2
- CREB5 | c.384C>A p.N128K (on ENST00000357727 / NM_182898.4; = p.N121K on NM_004904.3) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63217204; called by muse, mutect2, varscan2
- CRYZL1 | c.466-2A>T p.X156_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV51675798; called by muse, mutect2
- CSMD3 | c.4197G>T p.E1399D (on ENST00000297405 / NM_001363185.1; = p.E1295D on NM_052900.3) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.401); catalogued as COSV52096707; called by muse, mutect2, varscan2
- DMXL2 | c.8971C>T p.R2991* | Nonsense Mutation (SNP) | VAF 32/140 reads (23%) | catalogued as rs775750727, COSV51840432; called by muse, mutect2, varscan2
- DTX2 | c.1007C>A p.A336E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV56858664; called by muse, mutect2, varscan2
- EVI2A | c.600A>C p.K200N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs757823012, COSV55985469; called by muse, mutect2, varscan2
- FAM181A | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99967817; called by mutect2, varscan2
- FAM83B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368238775; called by muse, mutect2, varscan2
- FGB | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); catalogued as COSV57417388, COSV57418309; called by muse, mutect2, varscan2
- FLT1 | c.197T>C p.M66T | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1210263660, COSV56717099; called by muse, mutect2, varscan2
- FRMPD4 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV66211115; called by muse, mutect2, varscan2
- FRY | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.684); catalogued as COSV66564681; called by muse, mutect2, varscan2
- FURIN | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99184811; called by muse, mutect2
- GALNT14 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as rs766451616, COSV61102247; called by muse, mutect2, varscan2
- GREB1 | c.2401T>C p.C801R | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV52179991; called by muse, mutect2, varscan2
- GRIN2B | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV74204704; called by muse, mutect2, varscan2
- HGF | c.482+1G>A p.X161_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | catalogued as COSV55945112, COSV55953608; called by muse, mutect2
- HOXB8 | c.685_686insT p.P229Lfs*75 | Frame Shift Ins (INS) | VAF 20/127 reads (16%) | catalogued as COSV99493922; called by mutect2, pindel, varscan2
- HOXD8 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as COSV57484857; called by muse, mutect2, varscan2
- IGLV10-54 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.104); catalogued as COSV101135420; called by muse, mutect2
- IL1RL1 | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99293767; called by muse, mutect2, varscan2
- IRS1 | c.2861G>T p.W954L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV59333291; called by muse, mutect2, varscan2
- IRS4 | c.1817G>T p.R606L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as rs367909187, COSV64532547, COSV64533324; called by muse, mutect2, varscan2
- KEAP1 | c.1508T>A p.M503K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50260724; called by muse, mutect2, varscan2
- KIAA1549 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV54304906, COSV54321438; called by muse, mutect2, varscan2
- KMT2C | c.2329A>T p.S777C | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as COSV51281880, COSV51436441; called by muse, varscan2
- LAMA2 | c.739A>G p.R247G | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV70337668; called by muse, mutect2, varscan2
- LCE1F | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100542674, COSV57670371; called by muse, mutect2, varscan2
- LRRC15 | c.752A>T p.Y251F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.163); catalogued as COSV61649425; called by muse, mutect2, varscan2
- MCM4 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50621142; called by muse, mutect2, varscan2
- NCKAP5 | c.5527G>T p.A1843S | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as COSV100490671; called by muse, varscan2
- NCKAP5 | c.5526G>A p.M1842I | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100490680; called by muse, varscan2
- NEIL3 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52808350; called by muse, mutect2, varscan2
- NFASC | c.751G>A p.G251S (on ENST00000339876 / NM_001378329.1; = p.G262S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV58358086; called by muse, mutect2, varscan2
- NIFK | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV53534168; called by muse, mutect2, varscan2
- NLRP13 | c.701T>A p.V234E | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs763332938, COSV61619751; called by muse, mutect2, varscan2
- NLRP14 | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55063791, COSV99079099; called by muse, mutect2, varscan2
- NOD1 | c.378G>A p.V126= | Splice Region (SNP) | VAF 13/65 reads (20%) | catalogued as COSV56110635; called by muse, mutect2, varscan2
- NPAP1 | c.416A>T p.K139M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV61504116; called by muse, mutect2, varscan2
- NRCAM | c.2529C>G p.D843E (on ENST00000379028 / NM_001371124.1; = p.D827E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61030723; called by muse, mutect2
- OPALIN | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.04); catalogued as COSV64520285; called by muse, mutect2, varscan2
- OR5M3 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56565649; called by muse, mutect2, varscan2
- PALM | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52766559; called by muse, mutect2, varscan2
- PAPPA | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60277040; called by muse, mutect2, varscan2
- PCDHA5 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs529947743, COSV65353301; called by muse, mutect2, varscan2
- PCDHGA8 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.02); catalogued as COSV53894985; called by muse, mutect2, varscan2
- PDE4D | c.1879C>T p.P627S (on ENST00000340635 / NM_001104631.2; = p.P491S on NM_006203.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); catalogued as COSV57714489; called by muse, mutect2, varscan2
- PIK3CG | c.1602del p.T535Pfs*25 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as COSV63246064; called by mutect2, pindel, varscan2
- PLD5 | c.1240A>T p.K414* (on ENST00000442594; = p.K352* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV59132574; called by muse, mutect2, varscan2
- PPARGC1B | c.2746C>T p.R916* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as rs1233280221, COSV58525800; called by muse, mutect2, varscan2
- RENBP | c.110T>G p.M37R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV100128641; called by muse, mutect2, varscan2
- RGS9 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV52222800; called by muse, mutect2, varscan2
- RP1 | c.3749G>A p.C1250Y | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV55109545; called by muse, mutect2
- RTTN | c.4844C>T p.S1615L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV55340990; called by muse, mutect2, varscan2
- RYR2 | c.4724A>G p.H1575R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63659318; called by muse, mutect2
- S1PR1 | c.675C>A p.Y225* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100541725, COSV59512478; called by muse, mutect2, varscan2
- SALL3 | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV73305737; called by muse, mutect2, varscan2
- SCML2 | c.1787A>T p.H596L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52618177; called by muse, mutect2, varscan2
- SEC22A | c.294T>G p.Y98* | Nonsense Mutation (SNP) | VAF 51/182 reads (28%) | catalogued as COSV59370884; called by muse, mutect2, varscan2
- SEMA5A | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV66784050; called by muse, mutect2
- SHOC2 | c.1069A>G p.I357V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99509986; called by muse, mutect2, varscan2
- SOS2 | c.2986G>T p.G996* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | catalogued as COSV99365590; called by muse, varscan2
- SPTA1 | c.2272C>A p.H758N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV63748544; called by muse, mutect2, varscan2
- STK26 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 17/130 reads (13%) | catalogued as COSV61228726, COSV61230641; called by muse, mutect2, varscan2
- STS | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54265577; called by muse, mutect2, varscan2
- TAF6 | c.1774C>G p.P592A | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV59840517, COSV59841582; called by muse, mutect2, varscan2
- TAS2R16 | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as COSV50796791; called by muse, mutect2, varscan2
- TEKT4 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.377); catalogued as rs1169450175, COSV54622690; called by muse, mutect2
- TGS1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as rs756384821, COSV52698097; called by muse, mutect2, varscan2
- TNK1 | c.1686A>C p.R562S (on ENST00000576812 / NM_001251902.2; = p.R557S on NM_003985.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100247874; called by muse, mutect2, varscan2
- TTN | c.97768G>A p.E32590K (on ENST00000591111; = p.E25166K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | PolyPhen possibly damaging (0.552); catalogued as rs892921331, COSV59873721; called by muse, mutect2, varscan2
- UBQLN4 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV64144980; called by muse, mutect2, varscan2
- WASHC2A | c.2249A>G p.K750R | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99254539; called by muse, mutect2, varscan2
- WDFY3 | c.6151C>T p.R2051C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs773014413, COSV55692799; called by muse, mutect2
- WDR17 | c.1968T>C p.Y656= | Splice Region (SNP) | VAF 13/61 reads (21%) | catalogued as rs200212356, COSV54567628; called by muse, mutect2, varscan2
- XYLT1 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV54476570, COSV54496121; called by muse, mutect2
- ZMYM5 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | catalogued as COSV100562600; called by muse, mutect2
- ZNF804A | c.237T>A p.Y79* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV56434474; called by muse, mutect2
- ZWINT | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV59184796; called by muse, mutect2, varscan2
- BAP1 | c.1864T>A p.L622M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.146); called by muse, mutect2
- FTMT | c.246_247insG p.Q83Afs*23 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | called by mutect2, pindel
- GCM1 | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- IRX6 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KLHL28 | c.404del p.G135Vfs*56 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- MACC1 | c.1258dup p.W420Lfs*9 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.3675G>C p.L1225= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV55774604; called by muse, mutect2, varscan2
- ADRA2A | c.420C>T p.C140= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs995124796, COSV54526737; called by muse, mutect2
- BAP1 | c.1863C>T p.P621= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- CASS4 | c.114G>T p.L38= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100824579; called by muse, mutect2
- COL5A3 | c.1944C>T p.S648= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV53405830; called by muse, mutect2
- DMBT1 | c.2994A>C p.G998= (on ENST00000338354 / NM_001377530.1; = p.G499= on NM_004406.3) | Silent (SNP) | VAF 39/377 reads (10%) | catalogued as COSV57533489; called by muse, mutect2
- DYNC2H1 | c.2388G>T p.R796= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV62085617; called by muse, mutect2, varscan2
- FAM181A | c.357G>T p.R119= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99967818; called by mutect2, varscan2
- GDPD1 | c.165T>C p.N55= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99404893; called by muse, mutect2
- GPC5 | c.1311C>A p.I437= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV65574851, COSV65605015; called by muse, mutect2, varscan2
- GPC5 | c.1644A>T p.A548= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV65574856; called by muse, mutect2, varscan2
- HCN3 | c.1764G>T p.R588= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV61360262; called by muse, mutect2
- IGHV1-58 | c.141C>G p.T47= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs782175883; called by muse, mutect2, varscan2
- IL1RL1 | c.342A>G p.P114= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV99293772; called by muse, mutect2, varscan2
- KRI1 | c.1419G>T p.T473= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV57263462; called by muse, mutect2, varscan2
- LCE1F | c.318C>T p.C106= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs773642403, COSV57668757; called by muse, mutect2, varscan2
- LRP1B | c.4326A>T p.T1442= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV67184226; called by muse, mutect2, varscan2
- MAGEL2 | c.3749A>G p.*1250= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1336622266, COSV58565788; called by muse, mutect2
- MOGAT3 | c.765C>A p.T255= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV56172604; called by muse, mutect2
- MXRA5 | c.4812A>G p.Q1604= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV54223073; called by muse, mutect2, varscan2
- NCAM1 | c.504C>A p.V168= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs782494134, COSV57510057; called by muse, mutect2, varscan2
- NMUR2 | c.522C>T p.S174= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV54916930; called by muse, mutect2, varscan2
- NPAS3 | c.993T>C p.H331= (on ENST00000356141 / NM_001164749.2; = p.H299= on NM_022123.3) | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV60821367; called by muse, mutect2, varscan2
- OR2AG1 | c.186G>T p.L62= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs547097110, COSV56625256; called by muse, mutect2, varscan2
- OVCH1 | c.2157T>A p.I719= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as COSV58959210; called by muse, mutect2
- PCDH17 | c.1053C>A p.I351= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV64971505; called by muse, mutect2, varscan2
- TUBA3E | c.42C>A p.V14= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV57269453; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23177C>A | Intron (SNP) | VAF 19/163 reads (12%) | catalogued as rs531761554, COSV61404978, COSV61424638; called by muse, mutect2, varscan2
